Somatic mutation profile of tumor specimen C3L-01631-01 (aliquot CPT0091720009) from CPTAC case C3L-01631, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.8 years (20,745 days).
Specimen C3L-01631-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ae68208-5c2d-46d3-931e-6935d7fe5fed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01631-31 (Blood Derived Normal), aliquot CPT0093650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/621792e8-746e-465e-be5a-494ce3e20a8e

The open-access MAF lists 901 somatic variants for this specimen: 605 protein-altering or splice-affecting, 185 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 420, Silent 185, Frame Shift Del 112, Intron 67, Nonsense Mutation 24, Splice Site 16, Frame Shift Ins 16, RNA 15, Splice Region 11, 5'UTR 10, 3'UTR 9, 5'Flank 8.

Variants (750 of 901; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 110/194 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55950385; called by muse, mutect2, varscan2
- AC053503.6 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.226); catalogued as rs1392566732; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/184 reads (18%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD2 | c.1057C>T p.P353S (on ENST00000315906 / NM_001145400.2; = p.P435S on NM_139174.4) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs748165932; called by muse, mutect2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- AGL | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs756393699; called by muse, mutect2, varscan2
- AHSG | c.762C>T p.P254= | Splice Region (SNP) | VAF 23/67 reads (34%) | catalogued as rs776590678; called by muse, mutect2, varscan2
- AIRE | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM114639; called by muse, mutect2, varscan2
- AKAP9 | c.5348G>A p.R1783H (on ENST00000359028; = p.R1751H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/480 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as rs767106255, COSV62337694, COSV62340081; called by muse, mutect2, varscan2
- AL031777.2 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 70/280 reads (25%) | catalogued as rs773584959; called by pindel, varscan2
- AMHR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 167/540 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1306686763; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 90/306 reads (29%) | catalogued as rs34047276; called by mutect2, varscan2
- AP002748.5 | c.262del p.E88Nfs*6 | Frame Shift Del (DEL) | VAF 59/249 reads (24%) | catalogued as COSV59150426; called by mutect2, pindel, varscan2
- AP3M1 | c.378A>T p.E126D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62330975; called by muse, mutect2, varscan2
- APLP1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775793591, COSV99697843; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 22/296 reads (7%) | catalogued as rs773922861; called by mutect2, pindel
- ARHGAP33 | c.2282del p.G761Afs*35 | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | catalogued as rs774601323; called by mutect2, pindel, varscan2
- ARHGEF10 | c.659G>A p.R220H (on ENST00000398564; = p.R195H on NM_014629.4) | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.379); catalogued as rs376450525; called by muse, mutect2
- ARID1A | c.2231C>G p.S744* | Nonsense Mutation (SNP) | VAF 66/262 reads (25%) | catalogued as COSV61379101, COSV61381848; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 97/294 reads (33%) | catalogued as COSV61389445; called by mutect2, varscan2
- ART3 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as rs201551056; called by muse, mutect2, varscan2
- AS3MT | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as COSV54917929; called by muse, mutect2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 40/143 reads (28%) | catalogued as rs747712363; called by mutect2, varscan2
- ATG2A | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1277862185; called by muse, mutect2, varscan2
- BAG6 | c.2226dup p.T743Yfs*23 (on ENST00000676571; = p.T696Yfs*23 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 124/439 reads (28%) | catalogued as rs1174704559; called by mutect2, pindel, varscan2
- BAIAP2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as rs772891818, COSV58333220; called by muse, mutect2, varscan2
- BARHL1 | c.946del p.L316Wfs*184 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs752703018; called by mutect2, varscan2
- BTBD11 | c.2063C>T p.S688L (on ENST00000280758 / NM_001018072.2; = p.S225L on NM_001017523.2) | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as rs1401810839, COSV55016358; called by muse, mutect2, varscan2
- BTBD18 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs569933884; called by muse, mutect2
- C16orf54 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.951); catalogued as rs370898520, COSV100268589; called by muse, mutect2, varscan2
- C1orf56 | c.1005+3_1005+6del p.X335_splice | Splice Site (DEL) | VAF 19/63 reads (30%) | catalogued as rs1320396834; called by mutect2, pindel, varscan2
- C2orf16 | c.72dup p.I25Yfs*30 | Frame Shift Ins (INS) | VAF 49/224 reads (22%) | catalogued as rs766219691; called by mutect2, varscan2
- CALM3 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as rs1398867574, COSV52194552; called by muse, mutect2, varscan2
- CAMSAP2 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 148/630 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs753089995, COSV52675324; called by muse, mutect2, varscan2
- CAPN5 | c.466G>A p.A156T (on ENST00000456580; = p.A116T on NM_004055.5) | Missense Mutation (SNP) | VAF 108/407 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as rs374584917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBX2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1193695337; called by muse, mutect2
- CCDC105 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52964736; called by muse, mutect2
- CCT6A | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.499); catalogued as COSV99303456; called by muse, mutect2, varscan2
- CD207 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 118/375 reads (31%) | catalogued as rs1423107223; called by muse, mutect2, varscan2
- CDH10 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs376632889; called by muse, mutect2, varscan2
- CEL | c.619dup p.D207Gfs*59 (on ENST00000673714; = p.D204Gfs*59 on NM_001807.6) | Frame Shift Ins (INS) | VAF 49/216 reads (23%) | catalogued as rs754393686; called by mutect2, varscan2
- CHD3 | c.5578G>A p.V1860I (on ENST00000330494 / NM_001005273.3; = p.V1826I on NM_005852.4) | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs944136166; called by muse, mutect2
- CLCA2 | c.2670del p.N891Ifs*13 | Frame Shift Del (DEL) | VAF 45/153 reads (29%) | catalogued as rs768413031, COSV100991300; called by mutect2, pindel, varscan2
- CLCA4 | c.544del p.I182Sfs*56 | Frame Shift Del (DEL) | VAF 43/166 reads (26%) | catalogued as rs760255767; called by mutect2, varscan2
- CLCN6 | c.1138del p.V381Cfs*4 | Frame Shift Del (DEL) | VAF 64/220 reads (29%) | catalogued as COSV100411586; called by mutect2, pindel, varscan2
- CLCN7 | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 26/392 reads (7%) | catalogued as rs368724913, CM099583; called by muse, mutect2
- CNTN3 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs1311831022; called by muse, mutect2, varscan2
- COL10A1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754330529; called by muse, mutect2, varscan2
- CPT2 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99037289; called by muse, mutect2, varscan2
- CREB3L2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs377031866; called by muse, mutect2, varscan2
- CRYGD | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs1430734755; called by muse, mutect2
- CTAGE9 | c.1239_1241del p.E414del | In Frame Del (DEL) | VAF 143/667 reads (21%) | catalogued as rs775759605; called by pindel, varscan2
- CTSF | c.1166-7A>G | Splice Region (SNP) | VAF 68/234 reads (29%) | catalogued as rs1480417362; called by muse, mutect2, varscan2
- CUL9 | c.6935A>C p.N2312T | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1284211192; called by muse, mutect2, varscan2
- CUX1 | c.1727G>A p.R576H (on ENST00000437600 / NM_181500.4; = p.R578H on NM_001913.5) | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs1454862497; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | catalogued as rs772257590; called by mutect2, varscan2
- CYLC2 | c.417del p.D140Ifs*8 | Frame Shift Del (DEL) | VAF 33/136 reads (24%) | catalogued as rs761873747; called by mutect2, pindel, varscan2
- CYP4X1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as rs965440714, COSV64150805; called by muse, mutect2
- DCLK1 | c.2149G>A p.E717K (on ENST00000360631 / NM_001330072.2; = p.E410K on NM_001195416.2) | Missense Mutation (SNP) | VAF 30/347 reads (9%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.055); catalogued as COSV55174416; called by muse, mutect2
- DDX58 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs368263807; called by muse, mutect2
- DEPDC1 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 14/388 reads (4%) | catalogued as COSV63959422; called by muse, mutect2
- DERL1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.664); catalogued as COSV52364676; called by muse, mutect2, varscan2
- DICER1 | c.5207G>A p.R1736Q | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58616502, COSV58630622; called by muse, mutect2
- DIP2B | c.2286G>A p.M762I | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs1418334444; called by muse, mutect2
- DLC1 | c.1993C>T p.R665C (on ENST00000276297 / NM_001348081.2; = p.R228C on NM_006094.5) | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1218116906, COSV99365773; called by muse, mutect2, varscan2
- DLC1 | c.546del p.V183Lfs*5 | Frame Shift Del (DEL) | VAF 95/367 reads (26%) | catalogued as COSV52291120; called by mutect2, pindel, varscan2
- DNAH5 | c.4900T>C p.Y1634H | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230672757; called by muse, mutect2
- DNAH9 | c.6751G>A p.A2251T | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52334240; called by muse, mutect2, varscan2
- DNHD1 | c.11327G>A p.R3776H | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs780177086; called by muse, mutect2, varscan2
- DNMT3A | c.1234G>T p.G412W | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53053549; called by muse, mutect2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 25/233 reads (11%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DRP2 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs925364201, COSV100871931, COSV65811509; called by muse, mutect2, varscan2
- E2F3 | c.64del p.A22Rfs*18 | Frame Shift Del (DEL) | VAF 93/335 reads (28%) | catalogued as rs770338281; called by mutect2, pindel, varscan2
- E2F7 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV59741678; called by muse, mutect2
- ECHS1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763902393, COSV100881906; called by muse, mutect2, varscan2
- EIF4G3 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.312); catalogued as rs1461161250; called by muse, mutect2, varscan2
- EP400 | c.5722A>G p.I1908V | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1465466589; called by muse, mutect2, varscan2
- EPHA4 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs368252272; called by muse, mutect2, varscan2
- EPHB3 | c.441del p.F148Sfs*8 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs753303163; called by mutect2, pindel, varscan2
- EPS8L2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs1189395178; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 76/214 reads (36%) | catalogued as rs768793415; called by mutect2, varscan2
- ERN2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as rs746829866, COSV56832507; called by muse, mutect2, varscan2
- F8 | c.6932C>A p.P2311H | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1047644991, CM061741, COSV100371588; called by muse, mutect2
- FAH | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs959533704; ClinVar: uncertain significance; called by muse, mutect2
- FAM117A | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs566472842, COSV53634156; called by muse, mutect2, varscan2
- FAM184A | c.2509C>T p.R837W | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs772310108, COSV58858215, COSV58859076; called by muse, varscan2
- FAM83H | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs782062829; called by muse, mutect2, varscan2
- FAT2 | c.9962T>C p.F3321S | Missense Mutation (SNP) | VAF 134/387 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942494; called by muse, mutect2, varscan2
- FLNC | c.3866C>T p.T1289M | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs755896234, COSV57968713; called by muse, mutect2, varscan2
- FRMD4A | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs772563228, COSV52717882; called by muse, mutect2, varscan2
- GALC | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as CD962011, COSV54324005; called by muse, mutect2, varscan2
- GAPDHS | c.751C>A p.H251N | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55880207; called by muse, mutect2, varscan2
- GDAP1L1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs541262708; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as rs763147690; called by mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GPBAR1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); catalogued as rs201530699, COSV50307477; called by muse, mutect2, varscan2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs748011069, COSV52786506; called by mutect2, pindel
- GRB7 | c.663+8del | Splice Region (DEL) | VAF 55/272 reads (20%) | catalogued as rs760897750; called by mutect2, pindel, varscan2
- GUCA1A | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 154/503 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV50003940; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | catalogued as rs754540615; called by mutect2, varscan2
- HIC2 | c.899del p.G300Afs*17 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs1388756225, COSV68041693; called by mutect2, pindel, varscan2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as rs761197780; called by mutect2, varscan2
- HPS4 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 22/524 reads (4%) | catalogued as COSV61102591; called by muse, mutect2
- HUWE1 | c.6008C>T p.T2003M | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs782477771, COSV53343668; called by muse, mutect2
- IFIH1 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55126766; called by muse, mutect2
- IFT57 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs993528189, COSV52709428; called by muse, mutect2, varscan2
- IGSF9B | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368859731, COSV58071272; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 41/205 reads (20%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCE | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs1190349979; called by muse, mutect2, varscan2
- ITIH2 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 46/170 reads (27%) | catalogued as rs545967088, COSV64433717; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 67/246 reads (27%) | catalogued as rs1555369773; called by mutect2, pindel, varscan2
- JAKMIP1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs374764524; called by muse, mutect2, varscan2
- JAZF1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1290410969; called by muse, mutect2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 90/362 reads (25%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNG1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs367782891; called by muse, mutect2, varscan2
- KCNH8 | c.1826-1G>T p.X609_splice | Splice Site (SNP) | VAF 38/129 reads (29%) | catalogued as COSV60464125; called by muse, mutect2, varscan2
- KDM5B | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV99350254; called by muse, mutect2, varscan2
- KIAA0586 | c.7G>A p.V3M (on ENST00000619416 / NM_001244190.2; = p.V18M on NM_014749.5) | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1260723288; called by muse, mutect2, varscan2
- KIAA1217 | c.3503C>A p.S1168* | Nonsense Mutation (SNP) | VAF 19/198 reads (10%) | catalogued as COSV100286735; called by muse, mutect2
- KIAA1549 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs763901118; called by muse, mutect2, varscan2
- KIF13B | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 121/419 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs1416549201, COSV73054180; called by muse, mutect2, varscan2
- KIF17 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.211); catalogued as COSV99929444; called by muse, mutect2
- KIF26B | c.5905G>A p.V1969I | Missense Mutation (SNP) | VAF 114/535 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781292387, COSV63646165; called by muse, mutect2, varscan2
- KIF2B | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV52131459; called by muse, mutect2
- KLHL25 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs751616150; called by muse, mutect2, varscan2
- KRT71 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57292720; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 33/130 reads (25%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747643808; called by muse, mutect2, varscan2
- LARP4B | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776303473, COSV100295138; called by muse, mutect2, varscan2
- LGI1 | c.288-4G>A | Splice Region (SNP) | VAF 106/432 reads (25%) | catalogued as rs775903197; called by muse, mutect2, varscan2
- LMNA | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs59601651, COSV61541978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759106535, COSV53786736; called by muse, mutect2
- MADD | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774124659, COSV60623023; called by muse, varscan2
- MAGEE1 | c.77del p.G26Afs*87 | Frame Shift Del (DEL) | VAF 77/214 reads (36%) | catalogued as COSV99058316; called by mutect2, pindel, varscan2
- MAGEL2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs1417430051, COSV58565902; called by muse, mutect2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 28/212 reads (13%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP1B | c.6935G>A p.R2312H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.828); catalogued as rs148824055; called by muse, mutect2
- MAP2K4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62254869; called by muse, varscan2
- MAP4K5 | c.1502T>G p.V501G | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50161915; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs760012501; called by mutect2, varscan2
- MLXIPL | c.1811del p.P604Qfs*23 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs1554594043; called by mutect2, pindel, varscan2
- MOB2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748566114; called by muse, mutect2, varscan2
- MRNIP | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195007219; called by muse, mutect2, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MTMR4 | c.60del p.K21Rfs*3 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | catalogued as rs750261859; called by mutect2, pindel, varscan2
- MUC16 | c.19229C>A p.S6410Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.354); catalogued as COSV67489606; called by muse, mutect2
- MUC2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.02); catalogued as rs756094710, COSV61243087; called by muse, mutect2
- MUC5B | c.7112G>A p.R2371Q | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs745642384; called by muse, mutect2, varscan2
- MYO15A | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 144/559 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1262824456; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as rs763929397; called by mutect2, varscan2
- NAV2 | c.6734G>A p.C2245Y (on ENST00000396087 / NM_001244963.2; = p.C2186Y on NM_145117.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761522307; called by muse, mutect2, varscan2
- NELFA | c.718C>T p.P240S (on ENST00000542778; = p.P229S on NM_005663.5) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1472635772; called by muse, mutect2
- NEUROD6 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs371375986; called by muse, mutect2
- NFIA | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100963968; called by muse, mutect2
- NIPBL | c.7553A>G p.D2518G | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs756187678; called by muse, mutect2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 60/213 reads (28%) | catalogued as rs763440516; called by mutect2, varscan2
- NLRP5 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66763553, COSV66764615; called by muse, mutect2, varscan2
- NPAS4 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.778); catalogued as rs762113835, COSV60651828; called by muse, mutect2, varscan2
- NR2F1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV59067946; called by muse, mutect2, varscan2
- NRG1 | c.303C>T p.C101= (on ENST00000523534; = p.C248= on NM_013962.2) | Splice Region (SNP) | VAF 26/67 reads (39%) | catalogued as rs1364012586; called by muse, mutect2, varscan2
- NRIP1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 22/335 reads (7%) | catalogued as COSV59657517; called by muse, mutect2
- NTF4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs377553005; called by muse, mutect2, varscan2
- ONECUT3 | c.1443del p.G483Afs*128 | Frame Shift Del (DEL) | VAF 62/192 reads (32%) | catalogued as rs1481660248; called by mutect2, pindel
- OPLAH | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1464192824; called by muse, varscan2
- OR1I1 | c.861del p.F288Lfs*10 | Frame Shift Del (DEL) | VAF 43/347 reads (12%) | catalogued as rs757692298, COSV52919281; called by mutect2, pindel, varscan2
- OR2G6 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs370143527; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR52R1 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1256259002, COSV61888565, COSV61889247; called by muse, mutect2, varscan2
- OXCT2 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs746081956; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 57/226 reads (25%) | catalogued as rs751755759; called by mutect2, varscan2
- PCDH19 | c.3439G>T p.V1147F (on ENST00000373034 / NM_001184880.2; = p.V1099F on NM_020766.3) | Missense Mutation (SNP) | VAF 85/381 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV55257084; called by muse, mutect2, varscan2
- PCDHA10 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV56507957; called by muse, mutect2, varscan2
- PFKP | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV101127025; called by muse, mutect2
- PHKB | c.1929del p.G644Efs*2 | Frame Shift Del (DEL) | VAF 46/442 reads (10%) | catalogued as rs35494330; called by mutect2, pindel
- PKD1 | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 40/684 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs535676910, COSV99239106; ClinVar: likely benign; called by muse, mutect2
- PKHD1 | c.6928G>A p.G2310R | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280450484, COSV100582150; called by muse, mutect2, varscan2
- PLPPR3 | c.1774G>A p.V592M (on ENST00000520876 / NM_001270366.2; = p.V620M on NM_024888.2) | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV62461988; called by muse, mutect2, varscan2
- PLXNA4 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 31/350 reads (9%) | catalogued as COSV58129445, COSV99059469; called by muse, mutect2
- PNISR | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100984374; called by muse, mutect2, varscan2
- POLQ | c.3086A>T p.N1029I | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.232); catalogued as rs750152976; called by muse, mutect2
- POLR1C | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs758194396; called by muse, mutect2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 121/355 reads (34%) | catalogued as rs753626854; called by mutect2, varscan2
- PPIC | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141769515; called by muse, mutect2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 55/157 reads (35%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PRKAB1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs373173905; called by muse, mutect2, varscan2
- PRSS16 | c.1274C>A p.T425K | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756472444; called by muse, mutect2, varscan2
- PSD4 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV99831114; called by muse, mutect2, varscan2
- PTPN7 | c.21del p.R8Afs*7 (on ENST00000495688; = p.R47Afs*7 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 79/345 reads (23%) | catalogued as rs754051725; called by mutect2, pindel, varscan2
- PUM2 | c.883+2T>C p.X295_splice | Splice Site (SNP) | VAF 11/103 reads (11%) | catalogued as COSV57584654; called by muse, mutect2
- PXDN | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.392); catalogued as rs775831965, COSV99413979; called by muse, mutect2, varscan2
- PYGM | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 159/568 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as rs375233791; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs528799264, COSV99242422; called by muse, mutect2, varscan2
- RAP1B | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs370617266; called by muse, mutect2, varscan2
- RNASEL | c.1921A>T p.M641L | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.645); catalogued as rs1255666602; called by muse, mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- ROBO3 | c.571dup p.R191Pfs*61 | Frame Shift Ins (INS) | VAF 38/134 reads (28%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, varscan2
- RTL1 | c.2756A>G p.Q919R | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101128214; called by muse, mutect2
- RXFP1 | c.1870A>G p.M624V | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs757939741; called by muse, mutect2, varscan2
- RYR2 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63682810; called by muse, mutect2, varscan2
- SCN4A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 49/553 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs376523210; ClinVar: uncertain significance; called by muse, mutect2
- SEC63 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 35/466 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV64598588; called by muse, mutect2
- SEL1L2 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); catalogued as rs372260139; called by muse, mutect2, varscan2
- SFT2D3 | c.394T>C p.C132R | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs1303242270; called by muse, mutect2, varscan2
- SHANK3 | c.3659C>G p.A1220G | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.106); catalogued as rs1210992538; called by muse, mutect2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | catalogued as COSV53462966; called by mutect2, pindel, varscan2
- SHISA7 | c.1076del p.G359Afs*178 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | catalogued as rs1568449946; called by mutect2, pindel, varscan2
- SHISAL1 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs200825189; called by muse, mutect2, varscan2
- SIM1 | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs144468868; called by muse, mutect2, varscan2
- SIMC1 | c.379G>A p.A127T (on ENST00000443967 / NM_001308196.1; = p.A146T on NM_001308195.2) | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs368098647; called by muse, mutect2, varscan2
- SLC25A47 | c.438del p.M147Cfs*23 | Frame Shift Del (DEL) | VAF 169/662 reads (26%) | catalogued as COSV59925886; called by mutect2, pindel, varscan2
- SLC27A1 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.044); catalogued as rs754844700; called by muse, mutect2, varscan2
- SLC44A4 | c.1946A>G p.Y649C | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773722853; called by muse, mutect2, varscan2
- SLC5A4 | c.372+1del p.X124_splice | Splice Site (DEL) | VAF 45/201 reads (22%) | catalogued as COSV56670137; called by pindel, varscan2
- SLC8B1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs756760550; called by muse, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SOGA3 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV64106630; called by muse, mutect2, varscan2
- SPHK1 | c.875C>T p.A292V (on ENST00000392496 / NM_001355139.2; = p.A306V on NM_021972.4) | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs773839692, COSV100039175, COSV60063620; called by muse, mutect2, varscan2
- SPIRE2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344216110, COSV65555704; called by muse, mutect2, varscan2
- SQSTM1 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 24/493 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as CM146290; called by muse, mutect2
- SRC | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV62441767; called by muse, mutect2, varscan2
- SREBF2 | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1004518589; called by muse, mutect2
- ST3GAL4 | c.856G>A p.A286T (on ENST00000392669 / NM_001254758.1; = p.A282T on NM_006278.3) | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs550860098, COSV99917717; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 111/398 reads (28%) | PolyPhen probably damaging (1); catalogued as rs150577421; called by muse, mutect2, varscan2
- SYDE1 | c.782del p.P261Rfs*80 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | catalogued as rs778610532; called by mutect2, pindel, varscan2
- SYTL4 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 61/255 reads (24%) | catalogued as rs1202985842, COSV99343433; called by muse, mutect2, varscan2
- TACC2 | c.8054C>T p.A2685V (on ENST00000334433; = p.A763V on NM_006997.4) | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865827548; called by muse, mutect2
- TAF1A | c.1326del p.K442Nfs*5 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV61918901; called by mutect2, pindel, varscan2
- TAS2R8 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.811); catalogued as rs780864711; called by muse, mutect2, varscan2
- TBX18 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs753516864, COSV63736561; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM2 | c.4047G>T p.K1349N (on ENST00000518659 / NM_001122679.2; = p.K1110N on NM_001080428.3) | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101319167; called by muse, mutect2, varscan2
- TEP1 | c.4157G>A p.R1386Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs745328441; called by muse, mutect2, varscan2
- TIMM9 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV53621763; called by muse, mutect2
- TMEM132A | c.2329C>A p.P777T (on ENST00000453848 / NM_178031.3; = p.P778T on NM_017870.4) | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs955590225; called by muse, mutect2, varscan2
- TMEM184B | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs1174720053; called by muse, mutect2
- TMEM87A | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1389960306; called by muse, mutect2, varscan2
- TRIM14 | c.545del p.T182Rfs*11 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as COSV100419639; called by mutect2, pindel, varscan2
- TRIM42 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53885084; called by muse, mutect2
- TRIM61 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs1227195347; called by muse, mutect2, varscan2
- TRMT10C | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59305509; called by muse, mutect2, varscan2
- TRPV2 | c.1329del p.I444Sfs*23 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | catalogued as COSV100641106; called by mutect2, pindel, varscan2
- TTC19 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs750600560; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC34 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.29); catalogued as COSV69002138; called by muse, mutect2, varscan2
- TTLL2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1331266451, COSV53443505; called by muse, mutect2
- TYW3 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs1210032360; called by muse, mutect2, varscan2
- UBR4 | c.5980C>T p.P1994S | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs762153960; called by muse, mutect2, varscan2
- UCP3 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs138705669; called by muse, mutect2, varscan2
- USP38 | c.2844del p.K948Nfs*8 | Frame Shift Del (DEL) | VAF 66/256 reads (26%) | catalogued as COSV61024916; called by mutect2, pindel, varscan2
- VASH1 | c.12del p.K5Rfs*146 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1566680298, COSV99387951; called by mutect2, pindel
- VSIG2 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as rs1565440149; called by muse, mutect2, varscan2
- WNT7A | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776330990, COSV99034823; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as rs1403895317; called by mutect2, pindel, varscan2
- ZBTB4 | c.11del p.P4Lfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs765991494; called by mutect2, varscan2
- ZBTB41 | c.714del p.K238Nfs*4 | Frame Shift Del (DEL) | VAF 28/267 reads (10%) | catalogued as COSV100962778; called by mutect2, pindel
- ZC3HAV1L | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs758018737, COSV51964661; called by muse, mutect2, varscan2
- ZDHHC2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 75/330 reads (23%) | catalogued as rs898508235, COSV50497625; called by muse, mutect2, varscan2
- ZFAND5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV52988908; called by muse, mutect2, varscan2
- ZFP30 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 56/241 reads (23%) | catalogued as rs1022685018, COSV63622555; called by muse, mutect2, varscan2
- ZFYVE26 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143078443; called by muse, mutect2
- ZNF12 | c.2012A>G p.Y671C (on ENST00000405858 / NM_016265.4; = p.Y633C on NM_006956.3) | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as rs1562597539; called by muse, mutect2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 59/227 reads (26%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF875 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs774156728, COSV60990473; called by muse, mutect2, varscan2
- ZSWIM4 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 127/406 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV54324231; called by muse, mutect2, varscan2
- AAGAB | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACTB | c.984+2T>G p.X328_splice | Splice Site (SNP) | VAF 180/548 reads (33%) | called by muse, varscan2
- ADNP2 | c.3135del p.K1045Nfs*29 | Frame Shift Del (DEL) | VAF 71/286 reads (25%) | called by mutect2, pindel, varscan2
- AKAP7 | c.248A>T p.Y83F | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- AKAP8L | c.755T>G p.F252C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AKAP9 | c.7663T>A p.F2555I (on ENST00000359028; = p.F2531I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ALKBH5 | c.766_768dup p.L256dup | In Frame Ins (INS) | VAF 36/90 reads (40%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1684del p.R562Vfs*4 (on ENST00000458649 / NM_001367468.1; = p.R472Vfs*4 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 140/512 reads (27%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1310del p.P437Rfs*9 (on ENST00000458649 / NM_001367468.1; = p.P347Rfs*9 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 140/503 reads (28%) | called by mutect2, pindel, varscan2
- ANGPTL4 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ANKRD11 | c.3599_3600del p.K1200Sfs*3 | Frame Shift Del (DEL) | VAF 195/802 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2615A>G p.K872R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD12 | c.2949dup p.S984Ifs*7 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | called by mutect2, varscan2
- ANKRD17 | c.7771G>A p.A2591T | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD20A1 | c.3068T>C p.V1023A | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- ANKRD30A | c.3142dup p.I1048Nfs*2 (on ENST00000611781; = p.I992Nfs*2 on NM_052997.2) | Frame Shift Ins (INS) | VAF 44/169 reads (26%) | called by mutect2, pindel, varscan2
- ANLN | c.11T>A p.F4Y | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANPEP | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANXA13 | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2
- APOB | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 103/393 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP3 | c.623dup p.N209Qfs*103 | Frame Shift Ins (INS) | VAF 128/476 reads (27%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.034); called by muse, mutect2
- ARFIP2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- ASAP1 | c.2375del p.P792Lfs*20 | Frame Shift Del (DEL) | VAF 95/288 reads (33%) | called by mutect2, pindel, varscan2
- ATP4B | c.733del p.L245Wfs*26 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- ATXN7L2 | c.1196del p.P399Lfs*23 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | called by mutect2, pindel, varscan2
- AVL9 | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AXL | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- B3GNT5 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- BAZ1A | c.219del p.A74Qfs*12 | Frame Shift Del (DEL) | VAF 84/340 reads (25%) | called by mutect2, varscan2
- BCL3 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPNT2 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA1 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 73/238 reads (31%) | called by muse, varscan2
- BRD2 | c.715A>T p.N239Y | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- BST1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTAF1 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- BTBD18 | c.1037A>C p.N346T | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- C1orf216 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- C6orf52 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, varscan2
- CACNA1I | c.6541G>A p.A2181T | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CADPS | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CBFA2T2 | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.858del p.L287* | Frame Shift Del (DEL) | VAF 113/491 reads (23%) | called by mutect2, pindel, varscan2
- CCDC159 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCN4 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CD276 | c.1546G>T p.A516S (on ENST00000318443 / NM_001024736.2; = p.A298S on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CDHR3 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CDX1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2
- CELSR2 | c.4822A>C p.S1608R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- CEP85L | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- CHD4 | c.3344C>A p.A1115D (on ENST00000357008 / NM_001363606.2; = p.A1128D on NM_001273.5) | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRM2 | c.1023T>A p.N341K | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CHRM5 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIAO2A | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CIBAR2 | c.722del p.P241Lfs*18 | Frame Shift Del (DEL) | VAF 45/160 reads (28%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1566_1568del p.V523del | In Frame Del (DEL) | VAF 64/272 reads (24%) | called by pindel, varscan2
- CLK4 | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CLNK | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CLPX | c.673+2T>A p.X225_splice | Splice Site (SNP) | VAF 72/338 reads (21%) | called by muse, mutect2, varscan2
- CLSPN | c.3871G>C p.V1291L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.467); called by mutect2, varscan2
- COASY | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2
- COL6A6 | c.3146A>G p.H1049R | Missense Mutation (SNP) | VAF 120/362 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 74/320 reads (23%) | called by mutect2, pindel, varscan2
- COPA | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CREB3L2 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, varscan2
- CT47B1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 84/763 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CTSS | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 121/493 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CUL9 | c.6884A>T p.D2295V | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CYFIP1 | c.3125_3126del p.R1042Tfs*2 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | called by pindel, varscan2
- DCDC2 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2
- DCLRE1A | c.3073A>G p.S1025G | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- DDX51 | c.1750del p.Q584Sfs*3 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | called by mutect2, varscan2
- DDX58 | c.852dup p.F285Ifs*20 | Frame Shift Ins (INS) | VAF 24/210 reads (11%) | called by mutect2, pindel, varscan2
- DHX15 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- DICER1 | c.4458del p.K1486Nfs*4 | Frame Shift Del (DEL) | VAF 59/426 reads (14%) | called by mutect2, pindel, varscan2
- DLGAP4 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DNA2 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); called by muse, mutect2
- DOCK4 | c.4618del p.I1540Lfs*4 | Frame Shift Del (DEL) | VAF 85/321 reads (26%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.11429C>T p.T3810I | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- EGFR | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 150/428 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- EHBP1L1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELP1 | c.1594A>G p.T532A | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.366); called by muse, mutect2
- ELP3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EMC3 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2
- ERVV-2 | c.274T>A p.S92T | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.494); called by muse, mutect2
- ESYT1 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EWSR1 | c.250del p.Q84Rfs*80 | Frame Shift Del (DEL) | VAF 42/129 reads (33%) | called by mutect2, pindel, varscan2
- F2R | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM122A | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM168B | c.517del p.H173Tfs*63 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | called by mutect2, pindel, varscan2
- FBLN1 | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 79/742 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FBXL7 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- FIBP | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- FMN2 | c.4585-1G>T p.X1529_splice | Splice Site (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- FOXC1 | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- FOXJ2 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FRMPD3 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSIP2 | c.10954G>T p.A3652S | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FXR1 | c.1497T>A p.S499R | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GBP7 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GCNT4 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.156); called by muse, mutect2
- GEMIN5 | c.1987A>G p.T663A | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GNPTAB | c.3250-1G>A p.X1084_splice | Splice Site (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- GOLGA4 | c.4060G>A p.A1354T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- GPBP1L1 | c.452del p.K151Sfs*12 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- GRIK5 | c.245-1G>A p.X82_splice | Splice Site (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- H2AW | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 22/632 reads (3%) | called by muse, mutect2
- HCAR1 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL1 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- HIPK1 | c.3373T>G p.S1125A (on ENST00000369558 / NM_001369806.1; = p.S731A on NM_181358.2) | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- HIRIP3 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HK3 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2
- HNF1A | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 10/337 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2
- HNRNPU | c.845G>T p.W282L (on ENST00000283179; = p.W344L on NM_004501.3) | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HP1BP3 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- HSF1 | c.609_610insT p.G204Wfs*23 | Frame Shift Ins (INS) | VAF 91/365 reads (25%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- HSPA5 | c.1067T>G p.I356S | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HTATSF1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 60/214 reads (28%) | called by muse, mutect2, varscan2
- HTR2B | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HUWE1 | c.8879C>T p.A2960V | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGDCC3 | c.2168del p.P723Rfs*37 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- IL17RC | c.155dup p.L52Ffs*7 | Frame Shift Ins (INS) | VAF 56/603 reads (9%) | called by mutect2, pindel
- IL37 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IMPA2 | c.483_484del p.E162Dfs*17 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel
- INTS4 | c.2306T>C p.L769S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IQGAP1 | c.2640C>A p.D880E | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ITGB8 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 97/349 reads (28%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.1924A>G p.N642D (on ENST00000359125 / NM_172107.4; = p.N614D on NM_004518.6) | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KCNQ5 | c.1388A>C p.K463T | Missense Mutation (SNP) | VAF 105/429 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- KDM5A | c.2903G>A p.R968K | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2
- KIAA1109 | c.11464A>G p.R3822G | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by mutect2, varscan2
- KIAA1522 | c.773T>C p.L258S (on ENST00000373480 / NM_001198972.2; = p.L317S on NM_020888.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- KIAA1549 | c.4114C>T p.H1372Y | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF21B | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLHL26 | c.1104del p.Q369Sfs*22 | Frame Shift Del (DEL) | VAF 39/146 reads (27%) | called by mutect2, pindel, varscan2
- KLHL35 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.237); called by muse, mutect2
- KMT2B | c.1746_1747del p.P583Tfs*15 | Frame Shift Del (DEL) | VAF 54/224 reads (24%) | called by pindel, varscan2
- LAMA2 | c.6112A>G p.K2038E | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LAMA5 | c.2194C>A p.P732T | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.259); called by muse, mutect2
- LARS1 | c.3314G>A p.R1105Q (on ENST00000394434 / NM_020117.11; = p.R1078Q on NM_016460.3) | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- LRRC52 | c.134C>A p.T45N | Missense Mutation (SNP) | VAF 82/481 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- LSM14A | c.1037dup p.N346Kfs*3 | Frame Shift Ins (INS) | VAF 64/253 reads (25%) | called by mutect2, pindel, varscan2
- LY6D | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- LYST | c.9785-5del | Splice Region (DEL) | VAF 53/336 reads (16%) | called by mutect2, varscan2
- MACF1 | c.4841A>T p.Y1614F | Missense Mutation (SNP) | VAF 62/199 reads (31%) | called by muse, mutect2, varscan2
- MAD1L1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2
- MADD | c.2894del p.K965Rfs*16 | Frame Shift Del (DEL) | VAF 124/420 reads (30%) | called by pindel, varscan2
- MAMDC2 | c.190del p.E64Rfs*6 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | called by mutect2, pindel, varscan2
- MAN1A2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAN1C1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 157/536 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP7D2 | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MARCHF2 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM3AP | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MCMDC2 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MED13 | c.6191C>T p.A2064V | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MED15 | c.2143C>A p.L715I (on ENST00000263205 / NM_001003891.3; = p.L675I on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- MEF2D | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 14/433 reads (3%) | called by muse, mutect2
- MEMO1 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MORC2 | c.236C>A p.A79D (on ENST00000397641 / NM_001303256.3; = p.A17D on NM_014941.3) | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2
- MOSMO | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MUC4 | c.16208A>T p.Y5403F (on ENST00000463781 / NM_018406.7; = p.Y1167F on NM_004532.6) | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- MUSK | c.2326del p.Y776Ifs*92 | Frame Shift Del (DEL) | VAF 134/508 reads (26%) | called by mutect2, pindel, varscan2
- MYLK4 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MYO15B | c.4685T>G p.I1562S | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO5A | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NAT16 | c.215del p.G72Afs*33 | Frame Shift Del (DEL) | VAF 102/356 reads (29%) | called by mutect2, pindel, varscan2
- NAV1 | c.2090G>A p.S697N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- NCAPG2 | c.2015T>C p.F672S | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCBP2L | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NCOR2 | c.4559del p.G1520Afs*22 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- NECTIN4 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NIN | c.1773C>A p.H591Q | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NINL | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- NINL | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLGN3 | c.1484C>G p.A495G (on ENST00000358741 / NM_181303.2; = p.A475G on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- NLRC3 | c.2014A>T p.S672C | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP8 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- NPBWR2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPIPB11 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 69/685 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NRIP1 | c.2184dup p.E729Rfs*8 | Frame Shift Ins (INS) | VAF 38/160 reads (24%) | called by mutect2, varscan2
- NSFL1C | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- NTRK1 | c.1632+1G>A p.X544_splice | Splice Site (SNP) | VAF 59/570 reads (10%) | called by muse, mutect2, varscan2
- NUMBL | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- NUP205 | c.2254T>C p.Y752H | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP35 | c.933del p.D312Mfs*26 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- OAZ1 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OBI1 | c.776del p.N259Ifs*9 | Frame Shift Del (DEL) | VAF 52/197 reads (26%) | called by mutect2, pindel, varscan2
- OBSCN | c.7802G>T p.S2601I | Missense Mutation (SNP) | VAF 116/597 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OGA | c.1835C>A p.A612D | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T1 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 27/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR2Y1 | c.415dup p.H139Pfs*41 | Frame Shift Ins (INS) | VAF 53/220 reads (24%) | called by mutect2, pindel, varscan2
- PALB2 | c.1739A>C p.Y580S | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2
- PCDHA4 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 193/689 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PCDHB10 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PDE10A | c.2178+1G>A p.X726_splice | Splice Site (SNP) | VAF 93/348 reads (27%) | called by muse, mutect2, varscan2
- PDE3A | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PIGU | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PITPNM1 | c.884del p.P295Qfs*74 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- PLCB1 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLD4 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2
- PLEKHB2 | c.526T>C p.Y176H (on ENST00000409279; = p.Y175H on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PLEKHB2 | c.504del p.S170Afs*5 | Frame Shift Del (DEL) | VAF 52/214 reads (24%) | called by mutect2, varscan2
- PMPCA | c.888del p.I297Lfs*4 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel
- POLR1C | c.532del p.L178Wfs*76 | Frame Shift Del (DEL) | VAF 164/534 reads (31%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.1208A>T p.E403V | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PPIL1 | c.68T>A p.I23N | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- PRAMEF7 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PRC1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 77/270 reads (29%) | called by muse, mutect2, varscan2
- PRDM2 | c.2316del p.K772Nfs*4 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | called by mutect2, pindel, varscan2
- PRKD2 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PRKDC | c.10814del p.N3605Tfs*48 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, varscan2
- PRNP | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTCHD1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 197/732 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PTDSS2 | c.964dup p.L322Pfs*43 | Frame Shift Ins (INS) | VAF 18/178 reads (10%) | called by mutect2, pindel
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 100/377 reads (27%) | called by pindel, varscan2
- PTPN1 | c.132T>G p.N44K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP2A | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); called by muse, varscan2
- PXDNL | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- QRICH1 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); called by muse, mutect2
- QSOX1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- RAD54B | c.499+2T>A p.X167_splice | Splice Site (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- RANBP2 | c.6004G>A p.A2002T | Missense Mutation (SNP) | VAF 54/776 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.7212G>A p.W2404* | Nonsense Mutation (SNP) | VAF 234/1048 reads (22%) | called by muse, mutect2, varscan2
- RARA | c.1319del p.P440Rfs*203 | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by mutect2, varscan2
- RASGRP3 | c.1147A>T p.R383* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- RASGRP3 | c.1574G>A p.C525Y (on ENST00000402538 / NM_001349975.2; = p.C524Y on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM48 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RCVRN | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 29/409 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- REC8 | c.1073T>A p.L358Q | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- REC8 | c.1328C>A p.P443H | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- RFWD3 | c.1577G>T p.S526I | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGP1 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- RIBC1 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RIF1 | c.4514del p.K1505Rfs*18 | Frame Shift Del (DEL) | VAF 68/180 reads (38%) | called by mutect2, varscan2
- RUFY1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SALL3 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SATL1 | c.1298T>C p.V433A (on ENST00000395409; = p.V620A on NM_001012980.2) | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SBNO1 | c.3683del p.K1228Rfs*5 (on ENST00000420886; = p.K1227Rfs*5 on NM_018183.5) | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by mutect2, pindel, varscan2
- SBNO2 | c.3574C>T p.Q1192* | Nonsense Mutation (SNP) | VAF 143/456 reads (31%) | called by muse, mutect2, varscan2
- SCGB2A2 | c.243+4A>C | Splice Region (SNP) | VAF 32/431 reads (7%) | called by muse, mutect2
- SCN1A | c.5936C>T p.T1979I (on ENST00000303395 / NM_001202435.3; = p.T1968I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SCN1A | c.2423C>T p.T808I (on ENST00000303395 / NM_001202435.3; = p.T797I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, varscan2
- SELENON | c.1090del p.Q364Rfs*? | Frame Shift Del (DEL) | VAF 40/485 reads (8%) | called by mutect2, pindel
- SEPTIN2 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); called by muse, mutect2
- SETX | c.4516A>T p.M1506L | Missense Mutation (SNP) | VAF 115/423 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SEZ6L2 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); called by muse, mutect2
- SH3RF3 | c.2226_2227del p.P744Nfs*95 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by pindel, varscan2
- SHANK2 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 124/432 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIN3B | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SIX2 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 138/485 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC11A1 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); called by muse, mutect2
- SLC13A5 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SLC17A8 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SLC1A6 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SLC35F4 | c.1445G>T p.R482M (on ENST00000339762 / NM_001352015.2; = p.R446M on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- SLC38A3 | c.1315T>C p.S439P | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC38A4 | c.421T>A p.L141I | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMAD3 | c.1078T>C p.F360L | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCD2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMYD4 | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 18/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SON | c.4419A>G p.I1473M | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SPDYE5 | c.841A>C p.I281L | Missense Mutation (SNP) | VAF 24/700 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.117); called by muse, mutect2
- SPNS2 | c.1379T>A p.V460E | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SRCIN1 | c.45del p.M16Cfs*44 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel
- SSTR4 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- SSTR5 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ST7 | c.1436A>G p.K479R (on ENST00000265437 / NM_021908.3; = p.K456R on NM_018412.4) | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- STARD7 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SUCLG2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYNE4 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TAOK3 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2
- TAS2R39 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- TBC1D1 | c.682del p.V228Cfs*83 | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | called by mutect2, pindel, varscan2
- TDRD9 | c.1235+2T>A p.X412_splice | Splice Site (SNP) | VAF 69/212 reads (33%) | called by muse, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | called by mutect2, pindel
- TGFB1I1 | c.129G>T p.Q43H (on ENST00000394863 / NM_001042454.3; = p.Q26H on NM_015927.4) | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TLN2 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TLR8 | c.2537C>T p.A846V (on ENST00000218032 / NM_138636.5; = p.A864V on NM_016610.4) | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TLR9 | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- TM7SF3 | c.650_652del p.R217del | In Frame Del (DEL) | VAF 64/179 reads (36%) | called by mutect2, pindel, varscan2
- TMEM260 | c.986T>G p.F329C | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TMEM63B | c.1413+5G>T | Splice Region (SNP) | VAF 36/408 reads (9%) | called by muse, mutect2
- TNRC18 | c.8067del p.T2690Rfs*111 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- TNRC6B | c.3386C>T p.T1129I (on ENST00000454349 / NM_001162501.2; = p.T1076I on NM_015088.3) | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TOGARAM1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TPM4 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TPRKB | c.441+5G>A | Splice Region (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1870A>G p.M624V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TRIB2 | c.495C>G p.H165Q | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIML1 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- TRIP12 | c.5309A>C p.K1770T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.404); called by muse, mutect2
- TRPM5 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, varscan2
- TSC22D2 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TSPYL1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TST | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- TTN | c.71471A>C p.N23824T (on ENST00000591111; = p.N16400T on NM_003319.4) | Missense Mutation (SNP) | VAF 100/306 reads (33%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.63817T>A p.F21273I (on ENST00000591111; = p.F13849I on NM_003319.4) | Missense Mutation (SNP) | VAF 21/192 reads (11%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBA7 | c.2728A>T p.K910* | Nonsense Mutation (SNP) | VAF 64/229 reads (28%) | called by muse, mutect2, varscan2
- UBE2J1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 29/445 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UBE2K | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR1 | c.2300T>C p.V767A | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.294); called by muse, varscan2
- UBR7 | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- UCKL1 | c.1529A>T p.K510M | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- UHRF1BP1L | c.4220G>T p.W1407L | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- UHRF1BP1L | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ULK1 | c.2899C>G p.L967V | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- URB1 | c.4979_4980del p.R1660Qfs*19 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by mutect2, pindel, varscan2
- USP34 | c.7365_7367del p.E2456del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2
- VAC14 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- VIT | c.75T>A p.H25Q | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR46 | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNT8A | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- WWP2 | c.2238+2T>C p.X746_splice | Splice Site (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- XIRP1 | c.3689C>A p.P1230H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XPC | c.2188C>A p.L730M | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- XPNPEP2 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XYLB | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- YLPM1 | c.2508G>T p.Q836H | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZC2HC1B | c.332del p.P111Lfs*4 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- ZDHHC15 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZFYVE1 | c.1517+1G>A p.X506_splice | Splice Site (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- ZNF131 | c.366A>T p.E122D | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.23); called by muse, mutect2
- ZNF143 | c.1208G>C p.S403T | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ZNF143 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF169 | c.420del p.G141Efs*13 | Frame Shift Del (DEL) | VAF 89/314 reads (28%) | called by mutect2, pindel, varscan2
- ZNF28 | c.2039A>G p.Q680R | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2
- ZNF358 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF419 | c.1308del p.F436Lfs*151 | Frame Shift Del (DEL) | VAF 47/210 reads (22%) | called by mutect2, pindel, varscan2
- ZNF469 | c.6869A>G p.N2290S (on ENST00000437464; = p.N2318S on NM_001367624.2) | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF518B | c.1400del p.N467Ifs*15 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | called by mutect2, varscan2
- ZNF638 | c.2515A>G p.K839E | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF746 | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- ZNF821 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- ZNF831 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZPLD1 | c.105T>C p.P35= (on ENST00000466937 / NM_001329788.1; = p.P51= on NM_175056.2) | Splice Region (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- ZRSR2 | c.1212del p.K405Rfs*? | Frame Shift Del (DEL) | VAF 69/271 reads (25%) | called by mutect2, pindel, varscan2
- ABCC1 | c.456C>T p.I152= | Silent (SNP) | VAF 78/209 reads (37%) | catalogued as COSV60682314; called by muse, varscan2
- ACTN2 | c.1321C>T p.L441= | Silent (SNP) | VAF 37/631 reads (6%) | called by muse, mutect2
- ADCY5 | c.3115C>T p.L1039= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as rs1301161015; called by muse, mutect2, varscan2
- AFF3 | c.3246C>T p.H1082= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs1036133464; called by muse, mutect2
- AKAP17A | c.825G>A p.R275= | Silent (SNP) | VAF 83/321 reads (26%) | catalogued as rs745514043; called by muse, mutect2, varscan2
- ANXA11 | c.732G>A p.T244= | Silent (SNP) | VAF 62/172 reads (36%) | catalogued as rs201680859, COSV55419162; called by muse, mutect2, varscan2
- AP3M2 | c.297G>A p.E99= | Silent (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- ARHGAP23 | c.4458C>T p.R1486= | Silent (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.1068C>T p.D356= | Silent (SNP) | VAF 55/235 reads (23%) | catalogued as rs368446618, COSV63130612, COSV63131811; called by muse, mutect2, varscan2
- ARHGAP45 | c.1009C>T p.L337= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- ASAP1 | c.1470C>T p.R490= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as rs533438828; called by muse, varscan2
- ATG7 | c.1914C>G p.P638= | Silent (SNP) | VAF 108/366 reads (30%) | catalogued as COSV61612664; called by muse, mutect2, varscan2
- B3GALT6 | c.645C>T p.G215= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs1354160280; called by muse, mutect2, varscan2
- B4GALNT1 | c.1167C>A p.I389= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- BARHL1 | c.351C>T p.S117= | Silent (SNP) | VAF 14/373 reads (4%) | catalogued as COSV55038072; called by muse, mutect2
- BPHL | c.675C>T p.C225= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as rs748796244, COSV100984448, COSV66744618; called by muse, mutect2, varscan2
- BPIFB3 | c.273G>A p.E91= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, varscan2
- BRD1 | c.1999C>A p.R667= | Silent (SNP) | VAF 85/263 reads (32%) | called by muse, mutect2, varscan2
- BTAF1 | c.3108G>A p.K1036= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs1382410040; called by muse, varscan2
- C10orf71 | c.54C>T p.I18= | Silent (SNP) | VAF 61/196 reads (31%) | catalogued as rs368577905; called by muse, mutect2, varscan2
- C12orf56 | c.579C>A p.A193= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs1565754126; called by muse, mutect2, varscan2
- CALD1 | c.846C>T p.A282= | Silent (SNP) | VAF 118/398 reads (30%) | catalogued as rs562542239; called by muse, varscan2
- CARD10 | c.492C>T p.L164= | Silent (SNP) | VAF 100/298 reads (34%) | catalogued as rs767072413; called by muse, mutect2, varscan2
- CASZ1 | c.3528C>T p.Y1176= | Silent (SNP) | VAF 114/389 reads (29%) | catalogued as rs979714006; called by muse, mutect2, varscan2
- CCDC33 | c.627G>A p.Q209= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, varscan2
- CCDC51 | c.72C>G p.G24= | Silent (SNP) | VAF 50/164 reads (30%) | called by muse, mutect2, varscan2
- CELSR1 | c.8190G>A p.R2730= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- CEP250 | c.2709C>A p.A903= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- CHCHD4 | c.252G>A p.G84= (on ENST00000396914 / NM_001098502.2; = p.G97= on NM_144636.3) | Silent (SNP) | VAF 62/237 reads (26%) | catalogued as rs752834803, COSV55499577; called by muse, mutect2, varscan2
- CHD5 | c.2133G>A p.L711= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- CHM | c.891A>G p.K297= | Silent (SNP) | VAF 92/294 reads (31%) | called by muse, mutect2, varscan2
- CHRM2 | c.699A>G p.P233= | Silent (SNP) | VAF 48/522 reads (9%) | called by muse, mutect2
- CHST6 | c.858G>A p.A286= | Silent (SNP) | VAF 61/787 reads (8%) | catalogued as rs375043854; called by muse, mutect2
- CKAP2L | c.1911T>G p.L637= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- CLSPN | c.3870T>C p.P1290= | Silent (SNP) | VAF 31/212 reads (15%) | called by muse, mutect2, varscan2
- COG4 | c.1632G>A p.A544= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as rs771255200, COSV60423479; called by muse, mutect2, varscan2
- COX18 | c.42T>C p.P14= | Silent (SNP) | VAF 71/263 reads (27%) | called by muse, mutect2, varscan2
- CPSF1 | c.4155C>T p.H1385= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as rs782128990; called by muse, mutect2
- CREB3L1 | c.1254C>T p.S418= | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- CUX1 | c.3690C>T p.T1230= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as rs147364710, COSV99472405; called by muse, mutect2, varscan2
- CXCL5 | c.76C>T p.L26= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, varscan2
- CXCR6 | c.276C>A p.I92= | Silent (SNP) | VAF 115/390 reads (29%) | called by muse, mutect2, varscan2
- DDIT4L | c.516A>G p.S172= | Silent (SNP) | VAF 77/245 reads (31%) | called by muse, mutect2, varscan2
- DHCR7 | c.1017C>T p.G339= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs774757811, COSV100831761; ClinVar: likely benign; called by muse, mutect2, varscan2
- DICER1 | c.1017G>A p.E339= | Silent (SNP) | VAF 96/353 reads (27%) | catalogued as rs755007541; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC13 | c.1218T>C p.N406= | Silent (SNP) | VAF 73/221 reads (33%) | called by muse, mutect2, varscan2
- DYNLL2 | c.171C>T p.I57= | Silent (SNP) | VAF 19/349 reads (5%) | catalogued as rs751283300; called by muse, mutect2
- E2F8 | c.1509C>A p.P503= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- ELOA2 | c.1839C>T p.D613= | Silent (SNP) | VAF 72/260 reads (28%) | catalogued as rs750520652; called by muse, mutect2, varscan2
- ERICH3 | c.2433G>A p.A811= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs541437663; called by muse, mutect2, varscan2
- ESR2 | c.753C>T p.H251= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs770801445; called by muse, mutect2, varscan2
- ETV5 | c.900C>T p.C300= | Silent (SNP) | VAF 17/226 reads (8%) | catalogued as rs952232860, COSV60506247; called by muse, mutect2
- EYA2 | c.903C>T p.S301= | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as rs779509858, COSV57947655; called by muse, mutect2, varscan2
- FAM13C | c.366G>A p.V122= | Silent (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- FANCB | c.300A>G p.K100= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- FER1L6 | c.1392G>A p.S464= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs113087741; called by muse, mutect2, varscan2
- FGD5 | c.2304C>T p.S768= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs756502739; called by muse, mutect2, varscan2
- FLNB | c.2121A>T p.S707= | Silent (SNP) | VAF 139/502 reads (28%) | catalogued as rs368288478; called by muse, mutect2, varscan2
- FOXA1 | c.774C>T p.C258= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs776008770; called by muse, mutect2, varscan2
- FZD1 | c.1848G>A p.T616= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs1361239138, COSV55309360; called by muse, mutect2, varscan2
- GABRR1 | c.1155C>T p.C385= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as rs1216756964, COSV65618998; called by muse, mutect2, varscan2
- GCDH | c.1086T>C p.A362= | Silent (SNP) | VAF 60/552 reads (11%) | called by muse, mutect2, varscan2
- GLI2 | c.2460G>A p.E820= (on ENST00000361492 / NM_001374353.1; = p.E837= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- GLI2 | c.2769C>T p.G923= (on ENST00000361492 / NM_001374353.1; = p.G940= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1310224410; called by muse, mutect2, varscan2
- GRB7 | c.1422G>A p.L474= | Silent (SNP) | VAF 98/328 reads (30%) | called by muse, mutect2, varscan2
- GREB1L | c.2898G>A p.Q966= | Silent (SNP) | VAF 129/430 reads (30%) | called by muse, mutect2, varscan2
- GRID1 | c.1509G>T p.G503= | Silent (SNP) | VAF 68/250 reads (27%) | catalogued as COSV60048817; called by muse, mutect2, varscan2
- GRIP2 | c.288G>A p.A96= | Silent (SNP) | VAF 68/237 reads (29%) | catalogued as rs373332967; called by muse, mutect2, varscan2
- GUCY1A1 | c.795C>A p.S265= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as COSV99637583; called by muse, mutect2, varscan2
- HAS1 | c.1258C>T p.L420= | Silent (SNP) | VAF 128/437 reads (29%) | catalogued as COSV55789843; called by muse, mutect2, varscan2
- HEG1 | c.4137C>T p.D1379= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs781173052; called by muse, mutect2, varscan2
- HLA-C | c.846G>A p.T282= | Silent (SNP) | VAF 89/226 reads (39%) | catalogued as rs72558149; called by muse, mutect2, varscan2
- HMGXB3 | c.3579C>A p.I1193= (on ENST00000613459; = p.I947= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/594 reads (8%) | called by muse, mutect2
- IGFALS | c.687G>A p.A229= | Silent (SNP) | VAF 25/605 reads (4%) | catalogued as rs1230452131; called by muse, mutect2
- IL1RAPL1 | c.1554T>C p.I518= | Silent (SNP) | VAF 120/374 reads (32%) | catalogued as COSV100150429; called by muse, mutect2, varscan2
- INKA2 | c.726C>T p.T242= | Silent (SNP) | VAF 108/412 reads (26%) | catalogued as rs138822791; called by muse, mutect2, varscan2
- INTS11 | c.1725C>A p.S575= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- INTS12 | c.603T>C p.N201= | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2
- IRX1 | c.192C>T p.Y64= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100116131; called by muse, mutect2, varscan2
- IRX5 | c.474C>A p.T158= | Silent (SNP) | VAF 147/458 reads (32%) | called by muse, mutect2, varscan2
- ITGB4 | c.3759C>T p.Y1253= | Silent (SNP) | VAF 60/559 reads (11%) | catalogued as rs376494263; called by muse, mutect2, varscan2
- KCTD18 | c.75C>A p.A25= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- KIF5C | c.123C>T p.I41= | Silent (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- KMT2D | c.11853G>A p.Q3951= | Silent (SNP) | VAF 134/457 reads (29%) | called by muse, varscan2
- KNL1 | c.1932T>C p.S644= (on ENST00000346991 / NM_170589.5; = p.S618= on NM_144508.5) | Silent (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- LACTBL1 | c.12G>A p.R4= (on ENST00000618559; = p.R33= on NM_001289974.2) | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, varscan2
- LNX1 | c.1284T>C p.R428= (on ENST00000263925 / NM_001126328.3; = p.R332= on NM_032622.2) | Silent (SNP) | VAF 53/201 reads (26%) | called by muse, mutect2, varscan2
- LONP1 | c.2256C>T p.T752= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as rs371040522; called by muse, mutect2, varscan2
- LONP1 | c.1074G>A p.R358= | Silent (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- LPAR5 | c.984G>A p.A328= | Silent (SNP) | VAF 14/207 reads (7%) | called by muse, mutect2
- LRP1 | c.11691C>T p.D3897= | Silent (SNP) | VAF 130/475 reads (27%) | catalogued as rs569709680, COSV99676471; called by muse, mutect2, varscan2
- LRRC72 | c.654C>A p.A218= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.3993G>A p.E1331= | Silent (SNP) | VAF 30/288 reads (10%) | called by muse, mutect2, varscan2
- MCF2L | c.3192G>A p.A1064= (on ENST00000375608; = p.A1032= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as rs781656687; called by muse, mutect2, varscan2
- MEAK7 | c.708G>A p.V236= | Silent (SNP) | VAF 14/406 reads (3%) | called by muse, mutect2
- MED17 | c.510A>G p.S170= | Silent (SNP) | VAF 12/356 reads (3%) | catalogued as rs1479231013; called by muse, mutect2
- MEPCE | c.1611C>A p.P537= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs768295389, COSV99440235; called by muse, mutect2, varscan2
- MTA2 | c.562C>A p.R188= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as rs771442182; called by muse, mutect2, varscan2
- MYORG | c.1851G>A p.P617= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs760688755; called by muse, mutect2, varscan2
- NCKAP5L | c.3993G>T p.G1331= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- NEXMIF | c.2248T>C p.L750= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- NOCT | c.873T>C p.T291= | Silent (SNP) | VAF 86/332 reads (26%) | called by muse, mutect2, varscan2
- NSUN5 | c.1254C>T p.F418= | Silent (SNP) | VAF 82/295 reads (28%) | catalogued as rs1243403243, COSV53090813; called by muse, mutect2, varscan2
- NUDT11 | c.282C>T p.Y94= | Silent (SNP) | VAF 38/560 reads (7%) | called by muse, mutect2
- OAT | c.123T>C p.D41= | Silent (SNP) | VAF 130/466 reads (28%) | catalogued as rs376051303; ClinVar: uncertain significance; called by muse, varscan2
- OR1L1 | c.189C>T p.I63= (on ENST00000373686; = p.I13= on NM_001005236.3) | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as rs544493816; called by muse, mutect2, varscan2
- OR51A4 | c.714T>C p.A238= | Silent (SNP) | VAF 118/452 reads (26%) | called by muse, mutect2, varscan2
- OR6B1 | c.432C>T p.L144= | Silent (SNP) | VAF 76/254 reads (30%) | catalogued as rs377370623; called by muse, mutect2, varscan2
- PABPC3 | c.84C>T p.Y28= | Silent (SNP) | VAF 66/208 reads (32%) | catalogued as rs770302125, COSV55797306; called by muse, mutect2, varscan2
- PADI2 | c.1465C>T p.L489= | Silent (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1068G>A p.S356= | Silent (SNP) | VAF 32/260 reads (12%) | catalogued as rs1245489112, COSV56532757, COSV56541754; called by muse, mutect2, varscan2
- PCDHB16 | c.1125C>T p.S375= | Silent (SNP) | VAF 96/282 reads (34%) | catalogued as rs781893313, COSV53360079; called by muse, mutect2, varscan2
- PCNX2 | c.2397A>G p.S799= | Silent (SNP) | VAF 50/263 reads (19%) | called by muse, mutect2, varscan2
- PITRM1 | c.18G>A p.G6= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs751838757; called by muse, mutect2, varscan2
- PLCG2 | c.1881C>T p.F627= | Silent (SNP) | VAF 104/319 reads (33%) | catalogued as rs754739394, COSV63868535; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCH1 | c.3234C>A p.P1078= (on ENST00000340059 / NM_001130960.2; = p.P1070= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/270 reads (32%) | called by muse, mutect2, varscan2
- PLCL2 | c.3117G>A p.L1039= (on ENST00000615277 / NM_001144382.2; = p.L913= on NM_015184.5) | Silent (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- PNMA8B | c.1257G>A p.A419= | Silent (SNP) | VAF 51/250 reads (20%) | catalogued as rs1174646608, COSV66537888; called by muse, mutect2, varscan2
- PPM1H | c.522G>A p.L174= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as rs1425871953; called by muse, mutect2, varscan2
- PPP1R2B | c.447T>C p.N149= | Silent (SNP) | VAF 128/440 reads (29%) | catalogued as rs748240563; called by muse, mutect2, varscan2
- PRG4 | c.516T>C p.S172= | Silent (SNP) | VAF 49/318 reads (15%) | catalogued as rs1184330050, COSV66625424; called by muse, mutect2, varscan2
- PRG4 | c.2511T>C p.T837= | Silent (SNP) | VAF 36/475 reads (8%) | called by muse, mutect2
- PRPF40B | c.1767C>T p.D589= (on ENST00000380281; = p.D576= on NM_012272.3) | Silent (SNP) | VAF 88/313 reads (28%) | called by muse, mutect2, varscan2
- PSG6 | c.780C>A p.T260= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- PTPN20 | c.697C>T p.L233= | Silent (SNP) | VAF 26/719 reads (4%) | called by muse, mutect2
- QRSL1 | c.1266C>T p.T422= | Silent (SNP) | VAF 113/458 reads (25%) | called by muse, mutect2, varscan2
- RANBP2 | c.9390T>C p.H3130= | Silent (SNP) | VAF 48/215 reads (22%) | called by muse, mutect2, varscan2
- RBBP6 | c.2418T>C p.Y806= | Silent (SNP) | VAF 72/182 reads (40%) | called by muse, mutect2, varscan2
- RBMX2 | c.759C>A p.S253= | Silent (SNP) | VAF 27/492 reads (5%) | called by muse, mutect2
- REXO1 | c.3513C>T p.L1171= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs1181525255; called by muse, mutect2
- RFWD3 | c.222G>A p.P74= | Silent (SNP) | VAF 26/314 reads (8%) | catalogued as rs746152970, COSV63098062; called by muse, mutect2
- RNF11 | c.72T>A p.A24= | Silent (SNP) | VAF 70/210 reads (33%) | called by muse, mutect2, varscan2
- RPTOR | c.633A>G p.L211= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs746407644; called by muse, mutect2, varscan2
- RPUSD4 | c.909C>T p.G303= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs1484508136; called by muse, mutect2, varscan2
- RTL1 | c.1266C>T p.S422= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as rs1358949183, COSV66016908; called by muse, mutect2, varscan2
- SART1 | c.1506G>A p.Q502= | Silent (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- SCN3B | c.105C>T p.A35= | Silent (SNP) | VAF 71/253 reads (28%) | catalogued as rs368979661; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC24B | c.1899C>T p.N633= | Silent (SNP) | VAF 8/157 reads (5%) | catalogued as rs1288772987; called by muse, mutect2
- SEPTIN6 | c.624C>T p.N208= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs1382883257; called by muse, mutect2, varscan2
- SEPTIN6 | c.474G>T p.T158= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- SESTD1 | c.207C>T p.G69= | Silent (SNP) | VAF 60/276 reads (22%) | called by muse, mutect2, varscan2
- SFRP5 | c.229C>T p.L77= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- SHROOM2 | c.666C>T p.H222= | Silent (SNP) | VAF 115/414 reads (28%) | catalogued as rs865791837; called by muse, mutect2, varscan2
- SLAMF6 | c.957A>G p.K319= (on ENST00000368057 / NM_001184714.2; = p.K318= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/379 reads (21%) | called by muse, mutect2, varscan2
- SLC5A1 | c.15C>A p.T5= | Silent (SNP) | VAF 156/526 reads (30%) | called by muse, mutect2, varscan2
151 further variants in this file (0 protein-altering or splice-affecting, 40 silent, 111 other) are not listed here.
